Gene-level copy-number profile of tumor specimen TCGA-DD-AACX-01A from TCGA case TCGA-DD-AACX, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 66.6 years (24,329 days).
Specimen TCGA-DD-AACX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.bef37036-94a6-41dd-b323-51c706cc5a22.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-AACX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2d51b168-d046-4928-83a3-999464c14c50

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,046; copy number 2: 48,760; copy number 3: 4,969; copy number 4: 39; copy number 6: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-AACX-01A-11D-A40Q-01): tumor purity 0.91, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:213,817,751–214,187,773, 6 genes, copy number 6 (within-gene range 3–6): PROX1-AS1, LINC00538, PROX1, AC011700.1, AL606537.1, LINC02775.

Autosomal genes at a single copy (total copy number 1): 3,659. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
